Surgical pathology report (de-identified scan), TCGA case TCGA-05-4384, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4384-01A (Primary Tumor).

██████
██████:

Lung resection material with peripheral manifestation of an evidently mucin-forming adenocarcinoma (sample 1) with a tubulopapillary structure and partly a bronchioloalveolar growth pattern,.

Comment:

According to conventional histology, this is a peripheral mixed bronchopulmonary adenocarcinoma with an acinar and papillary component and partly bronchioloalveolar growth pattern (immunohistological analysis and confirmation to follow), which has focally infiltrated the visceral pleura in the region of the pleural adhesion zone. The tumor extends as far as the basal row of metal clamps. Subject to the immune profile, the TNM classification on the basis of this material is thus pT2 pNX pMX RX (C34.3, M8255/3).

1st follow-up report:

The immune profile (positivity for cytokeratin 7 and TTF1, focally also for cytokeratin 20 and also negativity for CDX2) confirms the bronchopulmonary adenocarcinoma.

Source: NCI Genomic Data Commons file 9b0e8212-dc29-434d-81b1-f83826fced50 (TCGA-05-4384.B70E95C5-2E6C-4409-8BBD-80E03E302B4C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).